Somatic mutation profile of tumor specimen TCGA-AB-2827-03B (aliquot TCGA-AB-2827-03B-01W-0728-08) from TCGA case TCGA-AB-2827, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.5 years (12,237 days).
Specimen TCGA-AB-2827-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9514a87-46e3-4eff-a5ea-aafeb8c6b37f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2827-11B (Solid Tissue Normal), aliquot TCGA-AB-2827-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/719f06f9-0f9c-497c-b7f4-7292f791518d

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTMR3 | c.623G>C p.S208T | Missense Mutation (SNP) | VAF 144/310 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as COSV60304584, COSV60309663; called by muse, mutect2, varscan2
- MYC | c.176C>T p.P59L (on ENST00000377970; = p.P74L on NM_002467.6) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294281543, COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2, varscan2
- SHTN1 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 4/114 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs905104409, COSV53381273; called by muse, mutect2
- SPESP1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs371688614; called by muse, mutect2, varscan2
- TSG101 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 114/300 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV52653309; called by muse, mutect2, varscan2
- EPHA10 | c.351C>T p.G117= | Silent (SNP) | VAF 110/963 reads (11%) | catalogued as COSV60402798; called by muse, varscan2
- KANK1 | c.1215C>G p.A405= | Silent (SNP) | VAF 23/162 reads (14%) | catalogued as COSV63216846; called by muse, mutect2, varscan2
- TAS2R4 | c.861G>A p.L287= | Silent (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- TMCO3 | c.1662C>T p.F554= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as rs779892736, COSV64809463; called by mutect2, varscan2
